Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1ZY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1ZY-06A (Metastatic).

ICD-O-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9

for 7/24/11

Patient: Xxxx
geb. *** **

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 85 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 1 mitosis per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a sheet like growth pattern. Melanophages are present.

Diagnosis: Parts of a malignant tumor, consistent with a metastasis of a melanoma.

Dr.

CQLF Site = SKIN

Primary Tumor Site Discrepancy not stated on path		

for 7/24/11

Source: NCI Genomic Data Commons file 127dcae2-2719-45f6-b82e-ffd5a84ea237 (TCGA-FS-A1ZY.B6F1051D-4991-4496-A211-2F4FEC470AAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).